Surgical pathology report (de-identified scan), TCGA case TCGA-24-1104, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1104-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

DOE

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital:

Patient:

Accession #

Taken:

Received:

Reported:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OVARY, LEFT, OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- TUMOR INVOLVES THE OVARIAN SURFACE
- VASCULAR LYMPHATIC INVASION IS IDENTIFIED

FALLOPIAN TUBE, LEFT, SALPINGECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

OVARY, RIGHT, OOPHORECTOMY

- NO EVIDENCE OF ADENOCARCINOMA IN THE OVARY
- SURFACE FIBROVASCULAR ADHESIONS
- METASTATIC SEROUS ADENOCARCINOMA PRESENT IN MESOVARIAN TISSUE

FALLOPIAN TUBE, RIGHT, SALPINGECTOMY

- NEGATIVE FOR ADENOCARCINOMA

SOFT TISSUE , LEFT PELVIC SIDE WALL, BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA

OMENTUM, BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA

SMALL INTESTINE, RESECTION

- METASTATIC SEROUS ADENOCARCINOMA INVOLVING ENTIRE THICKNESS OF INTESTINAL WALL
- RESECTION MARGINS FREE OF TUMOR
- METASTATIC SEROUS ADENOCARCINOMA IN THREE OF THREE LYMPH NODES (3/3)

LYMPH NODES, SPLENIC FLEXURE, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA IN TWO OF TWO LYMPH NODES (2/2)

[page 2 of 3]
Patient Name:

DOB:

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

J.***

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up specimen labeled 'left adnexa,' consisting of a partially cystic ovary, 13.5 x 9.5 x 6 cm, weighing 430 grams. Serially sectioned to reveal a tan to tan-yellow cut surface. Representative frozen (FS1) submitted for tumor bank and . Rest for permanents," by .

FS1: Adnexa, left, biopsy
- "Carcinoma," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a year old woman with enlarged left adnexa and pelvic nodule, supraclavicle lymph node biopsy showed non-small cell carcinoma

Specimen(s) Received:

- A: LEFT OVARY AND TUBE
- B: RIGHT OVARY AND TUBE
- C: LEFT PELVIC SIDE WALL
- D: OMENTUM, ROUTINE
- E: SMALL BOWEL
- F: SPLENIC FLEXURE

Gross Description

The specimens are received in six formalin-filled containers, each labeled with the patient's name. The first container is labeled "left adnexa." It contains a tan, lobulated mass, weighing 430 grams. The outer surface is tan to hemorrhagic and irregular with possible tumor present. The specimen was previously sliced. The surface is inked. Sectioning shows the cut surface is tan to yellow-tan slightly lobulated, with cystic areas. Some areas show a light yellow, edematous, trabeculated consistency. Focal hemorrhage is noticed. A structure resembling fallopian tube is identified attaching to the tumor. In the container there is a cassette labeled "FS1" which holds the frozen section remnant. Labeled A1 to A4 - tumor (A1 and A3 tumor with possible fallopian tube); A5, A6 - white-tan to yellow area; A7, A8 - solid area; A9, A10 - cystic areas; A11, A12 - yellow spongy area; A13 - large cystic areas; A14 - frozen remnant. Jar 2.

The second container is labeled "right adnexa." It contains a 6 x 2.7 x 0.7 cm, yellow to tan to hemorrhagic irregular soft tissue fragment. A possible ovary is identified which measures 2.7 x 2 x 0.6 cm. The outer surface is pink-tan and smooth. Sectioning shows the cut surface is white-gray and smooth. A fallopian tube measures 2 cm in length, 0.4 cm in diameter, with an unremarkable appearance. In the adipose tissue, a firm nodule is identified measuring 1 x 0.7 x 0.3 cm. Labeled B1 to B3 - ovary and fallopian tube; B4 - bisected firm nodule. Jar 1.

[page 3 of 3]
Patient Name:

DOB:

The third container is labeled "left pelvic side wall." It contains two tan to hemorrhagic, irregular soft tissue fragments measuring 2 x 1 x 0.7 cm and 3 x 2.5 x 0.5 cm. On examination, two firm nodules are identified, 1.5 cm and 1.9 cm in greatest dimension. Sectioning shows the nodule has a white-tan, smooth cut surface. Labeled C1. Jar 1.

The fourth container is labeled "omentum." It contains two fragments of yellow adipose tissue consistent with omentum measuring 15 x 11.5 x 1.5 cm and 5.5 x 4 x 1 cm. On examination, four firm nodules are identified, measuring 0.3 to 1.1 cm in greatest dimension. Sectioning shows they have a well circumscribed, white-gray, firm cut surface. Labeled D1, D2. Jar 2.

The fifth container is labeled "small intestine." It contains a 35 cm in length, 4.3 cm in circumference segment of small bowel with attached mesentery measuring 14 x 3 x 1 cm. The serosa is pink-tan with extensive adhesions to adhere the small bowel to each other. Multiple white-gray small nodules are present on the surface of the serosa. There is a sutured area. Sectioning shows this area has a submucosal white-gray nodule with hemorrhage. Opening of the remaining small bowel shows the mucosa is pink-tan with prominent intestinal folds. No polyps or other abnormalities are identified. The bowel wall measures 0.2 cm in thickness. In the mesentery there is a 2 x 1.5 x 0.8 cm, white-gray, firm area noted. Labeled E1, E2 - serosal nodules; E3 - sutured area; E4 - mesentery solid area; E5 - resection margin. Jar 2.

The sixth container is labeled "splenic flexure." It contains a 7 x 5.5 x 2 cm yellow, lobulated adipose tissue. On examination, two white-gray, firm nodules are identified measuring 0.6 x 0.3 x 0.3 cm and 2.5 x 1.8 x 1.6 cm. Labeled F1, F2. Jar 2.

Source: NCI Genomic Data Commons file 6110c4b8-073b-4f11-acbf-852522d72365 (TCGA-24-1104.4991D5F7-0259-430F-AFF7-1307DF563E41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).